Somatic mutation profile of tumor specimen TARGET-10-PATGYH-09A (aliquot TARGET-10-PATGYH-09A-01D) from TARGET case TARGET-10-PATGYH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.3 years (5,959 days).
Specimen TARGET-10-PATGYH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e701fac8-8904-424b-aabe-093433db1e92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATGYH-14A (Bone Marrow Normal), aliquot TARGET-10-PATGYH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d8b36d6-6a77-4b78-b679-5419f8bc6db7

The open-access MAF lists 25 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 5, Silent 5, Frame Shift Del 2, Splice Site 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPN1 | c.1231C>T p.R411C (on ENST00000270460 / NM_001321263.1; = p.R385C on NM_013333.3) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs753965980, COSV50036156; called by muse, mutect2, varscan2
- FANK1 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs781154409, COSV64161130; called by muse, mutect2
- KCNT2 | c.1122-1G>T p.X374_splice | Splice Site (SNP) | VAF 23/47 reads (49%) | catalogued as COSV54071794; called by muse, mutect2, varscan2
- LRRC7 | c.4712G>A p.R1571H (on ENST00000651989 / NM_001370785.2; = p.R1491H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50431409; called by muse, mutect2, varscan2
- LRRK1 | c.6034C>T p.R2012C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs780306812, COSV99443715; called by muse, mutect2
- NOTCH1 | c.2613C>A p.N871K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.279); catalogued as COSV53039396; called by muse, mutect2
- NXF1 | c.1373_1379delinsAA p.T458Kfs*9 | Frame Shift Del (DEL) | VAF 55/123 reads (45%) | catalogued as COSV53673011; called by pindel, varscan2*
- TCN1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs745904987, COSV57252660; called by muse, mutect2, varscan2
- XKR4 | c.679G>C p.A227P | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV59307256; called by muse, mutect2, varscan2
- ZNF264 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as rs775243894, COSV54041250; called by muse, mutect2, varscan2
- C3 | c.3853G>T p.D1285Y | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- COLGALT1 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SETD2 | c.4276_4279del p.K1426Lfs*5 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | called by pindel, varscan2
- SMC3 | c.2435_2436insGCAG p.L814Tfs*5 | Frame Shift Ins (INS) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- COL9A1 | c.2397T>C p.G799= | Silent (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- DNAH5 | c.5328T>C p.D1776= | Silent (SNP) | VAF 40/77 reads (52%) | called by muse, mutect2, varscan2
- KDM4B | c.846C>T p.H282= | Silent (SNP) | VAF 67/143 reads (47%) | catalogued as rs771691022; called by muse, mutect2, varscan2
- MCC | c.1977C>T p.A659= | Silent (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- TTC21A | c.3129G>A p.Q1043= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1407904203; called by muse, mutect2, varscan2
- LDLRAP1 | c.748-198G>A | Intron (SNP) | VAF 10/14 reads (71%) | catalogued as rs574238412; called by muse, varscan2
- MYL1 | c.-8A>G | 5'UTR (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- SORBS1 | c.2128+713G>T | Intron (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- TRMU | c.772+130C>T | Intron (SNP) | VAF 3/13 reads (23%) | catalogued as rs1039877769; called by muse, mutect2
- TXK | c.784+68C>T | Intron (SNP) | VAF 6/35 reads (17%) | catalogued as rs756778982; called by muse, mutect2, varscan2
- ZNF333 | c.511+1651C>T | Intron (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
